Somatic mutation profile of tumor specimen TARGET-10-PASSSR-09A (aliquot TARGET-10-PASSSR-09A-01D) from TARGET case TARGET-10-PASSSR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,878 days).
Specimen TARGET-10-PASSSR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7092eb9f-6c6b-40f1-a232-cf88ff2623ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASSSR-10A (Blood Derived Normal), aliquot TARGET-10-PASSSR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4195456a-c150-4f62-8ca3-211ca475ef7f

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 5, Silent 3, Nonsense Mutation 2, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5722G>A p.E1908K | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs543742946, COSV64670715; called by muse, mutect2, varscan2
- AKAP3 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs199800327, COSV57417467; called by muse, mutect2, varscan2
- ALOX15B | c.2020G>A p.V674I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs201702180, COSV66480213; called by muse, mutect2, varscan2
- CDK10 | c.547G>A p.G183S (on ENST00000353379 / NM_052988.5; = p.G112S on NM_052987.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759891268, COSV57048904; called by muse, mutect2, varscan2
- FAM47A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs764123221, COSV60495125; called by muse, mutect2, varscan2
- NOTCH1 | c.7326_7327insCCAAGACGTTAAAAGGGC p.D2442_V2443insPRR* | Nonsense Mutation (INS) | VAF 8/35 reads (23%) | catalogued as COSV53055489, COSV53060136, COSV53088130, COSV53092816, COSV53101392, COSV53111136; called by mutect2, pindel*
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2, varscan2
- SLC5A2 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.911); catalogued as rs753600896, CM034967, COSV57894811; called by muse, mutect2, varscan2
- CCND3 | c.794_826del p.P265_S275del | In Frame Del (DEL) | VAF 5/24 reads (21%) | called by pindel, varscan2*
- HMGB1 | c.329_330insGACTTCC p.P111Tfs*16 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.7526_7542del p.F2509* | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- NRCAM | c.3600T>A p.V1200= (on ENST00000379028 / NM_001371124.1; = p.V1079= on NM_005010.4 and 21 other RefSeq transcripts) | Splice Region (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- PHKB | c.1731G>A p.P577= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs201607512; called by muse, mutect2, varscan2
- PRAG1 | c.3171G>A p.S1057= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100422481; called by muse, mutect2, varscan2
- RHBDF1 | c.225G>A p.T75= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs760277372, COSV51958043; called by muse, mutect2, varscan2
- DDHD2 | c.1344+65T>C | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as rs898462018; called by muse, mutect2, varscan2
- ERC2 | c.1075-45G>A | Intron (SNP) | VAF 15/32 reads (47%) | catalogued as rs368640943; called by muse, mutect2, varscan2
- GOLGA6L2 | c.*58G>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs956739814; called by muse, mutect2, varscan2
- NPAS3 | c.558+32G>A | Intron (SNP) | VAF 25/132 reads (19%) | catalogued as rs775345591, COSV58119518; called by muse, mutect2, varscan2
- REEP4 | c.418-160delinsAGG | Intron (INS) | VAF 44/103 reads (43%) | catalogued as COSV57941922; called by pindel, varscan2*
- STX2 | c.280+472A>G | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
